Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4TK, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4TK-01A (Primary Tumor).

**Surgical Pathology
REVISED REPORT (addendum included)**

Requested by:

TISSUE DESCRIPTION:

Right middle lobe lung (4.8 x 1.2 x 1 cm) and right lower lobe lung with portion of middle lobe and posterior segment of right upper lobe (250 grams) and superior mediastinal (right lower paratracheal), inferior mediastinal (subcarinal, right lower paratracheal) and N1 (interlobar) lymph nodes

A1, A2, A3, A4, B1, B2, B3, B4, B5, B6, B7, B8, B9, B10

DIAGNOSIS:

Lung, right lower lobe with portion of middle lobe and posterior segment of right upper lobe, lobectomy: Invasive grade 4 (of 4) adenocarcinoma, with sarcomatoid differentiation, forming a 3.5 x 3.5 x 3 cm mass centered on the interlobar fissure and involving both upper and lower lobes. The bronchial margin and multiple (3) intrapulmonary peribronchial lymph nodes are negative for tumor.

Lung, right middle lobe, wedge excision: Atypical lymphoplasmacytic infiltrate, suspicious for low grade B-cell lymphoma. Definitive diagnosis and classification will be reported in an addendum.

Lymph nodes, N1, excision: Multiple N1 (3 of 3 interlobar) lymph nodes involved by metastatic adenocarcinoma.

Lymph nodes, superior, inferior mediastinal, excision: Multiple superior mediastinal (2 right lower paratracheal), inferior mediastinal (2 subcarinal, 2 paraesophageal) lymph nodes are negative for tumor.

ADDENDUM:

Immunoperoxidase studies were performed on paraffin sections of the right middle lobe biopsy using antibodies directed against the following antibodies: CD20, CD3, kappa and lambda immunoglobulin light chains. There is a mixed population of CD20-positive B-lymphocytes and CD3-positive T-lymphocytes distributed in a pattern typical of reactive hyperplasia. A polytypic pattern of immunoreactivity for immunoglobulin light chains is seen in mature plasma cells. The findings support a diagnosis of reactive lymphoid hyperplasia.

1CD-0-3

adenocarcinoma, NOS 8/40/3

Pth: Site: lung, NOS C34.9

CRCF lung, lower lobe C34.3

hw
10/31/12

Source: NCI Genomic Data Commons file f9994c83-88ef-42f7-ab03-73d8b6166582 (TCGA-MP-A4TK.D590727D-0D9F-4986-A41F-A5031C432967.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).